Somatic mutation profile of tumor specimen C3L-01210-54 (aliquot CPT0166140002) from CPTAC case C3L-01210, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 64.4 years (23,506 days).
Specimen C3L-01210-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25b9404b-73bc-444e-9215-30d423bb9e8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01210-50 (Buccal Cell Normal), aliquot CPT0166180003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08fa253f-b2d0-4c7f-9575-2d01d4f0bf49

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TTN | c.12103C>T p.P4035S (on ENST00000591111; = p.P3989S on NM_003319.4) | Missense Mutation (SNP) | VAF 34/91 reads (37%) | catalogued as rs756368092, COSV100633475; called by muse, mutect2, varscan2
- ZAN | c.1486G>A p.V496I | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.85); PolyPhen benign (0.25); catalogued as rs988782745, COSV100770129; called by muse, mutect2
- C16orf96 | c.2418G>A p.E806= | Silent (SNP) | VAF 40/123 reads (33%) | catalogued as rs1337874719; called by muse, mutect2, varscan2
